Surgical pathology report (de-identified scan), TCGA case TCGA-AD-5900, project TCGA-COAD (Colon Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AD-5900-01A (Primary Tumor).

[page 1 of 2]
TCGA-AD-5900

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

Right colon, segmental resection:

Tumor Characteristics:

Histologic type: Adenocarcinoma, with focal mucinous features.

Location of tumor: Right colon.

Size: 3.2 x 2.4 x 0.5 cm.

Grade (If applicable to tumor type): Low-grade (moderately differentiated).

Lymphovascular space invasion: No.

Perforation of visceral peritoneum: No.

Presence of mesenteric deposits: No.

Depth of invasion/extent of invasion: Tumor penetrates into superficial muscularis propria.

Surgical Margin Status:

Proximal margin: Negative by 8.2 cm.

Distal margin: Negative by 5.4 cm.

Deep (radial) margin: N/A, tumor does not erupt serosal surface.

Lymph Node Status:

Total number of lymph nodes examined: 11.

Total number of lymph nodes containing metastatic carcinoma: 0 (0/11).

Other:

1. Other significant findings: Tumor arises within tubular adenoma with high-grade dysplasia.

2. TNM stage: T2 N0 MX.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: ascending colon mass; high grade dysplasia

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right colon

CODES:

[page 2 of 2]
GROSS DESCRIPTION:

Received in one container labeled [REDACTED] and right colon a previously opened right colectomy specimen received for research. The terminal ileum measures 3.5 x 1.7 cm in diameter, the cecum and colon together measure 12.1 x 6.1 cm in diameter and the attached appendix measures 2.5 x 0.6 cm. The specimen is covered by a moderate amount of pericolic adipose tissue. On opening there is a 3.2 x 2.4 x 0.5 cm tan firm raised mass, 5.4 cm from the distal margin and 8.2 cm from the proximal margin. On section the lesion has a solid tan cut surface and is 0.4 cm thick. Grossly it does not perforate through the wall. The remainder of the lumen is lined by normal appearing tan mucosa. The appendix is grossly uninvolved by lesion.

After using the Reveal solution, ten lymph nodes are identified ranging from 0.3 x 0.2 x 0.1 cm to 1.5 x 0.9 x 0.6 cm. Representative sections are submitted as follows: 1--proximal margin; 2--distal margin; 3-5--representative sections of lesion; 6--representative appendix; 7--representative ileocecal valve; 8--one node sectioned; 9--three whole nodes; 10-12--two whole nodes in each cassette. Two cassettes for research labeled [REDACTED]

Source: NCI Genomic Data Commons file 88d31c94-959d-4b1a-b057-77337a4c00a3 (TCGA-AD-5900.DFE40B96-EB9B-4544-A87D-9ABC80F8A357.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).